Somatic mutation profile of tumor specimen C3L-03635-01 (aliquot CPT0238530008) from CPTAC case C3L-03635, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.7 years (23,274 days).
Specimen C3L-03635-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 479537cb-5cb4-409c-a7a7-0b82556b7e40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03635-31 (Blood Derived Normal), aliquot CPT0238560002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce404079-1486-4782-b1b1-e7d82af6bc88

The open-access MAF lists 64 somatic variants for this specimen: 41 protein-altering or splice-affecting, 17 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 17, Intron 3, Splice Site 1, Nonsense Mutation 1, Nonstop Mutation 1, 5'UTR 1, Splice Region 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRX | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 77/870 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771450991; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 75/603 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.526T>A p.C176S | Missense Mutation (SNP) | VAF 121/644 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs967461896, CM165714, COSV52681947, COSV52682539, COSV52736779, COSV52752470; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.3100C>T p.L1034F | Missense Mutation (SNP) | VAF 28/359 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as COSV51398434; called by muse, mutect2
- CDH9 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 38/738 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1402112195, COSV50251062, COSV50289480; called by muse, mutect2
- CUBN | c.2112G>A p.S704= | Splice Region (SNP) | VAF 54/832 reads (6%) | catalogued as rs774463666, COSV64716375; called by muse, mutect2
- DHX36 | c.1147A>G p.M383V | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs754937391, COSV57674533; called by muse, mutect2
- DNMT1 | c.3245G>A p.R1082H | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as rs377078524; ClinVar: uncertain significance; called by muse, mutect2
- GPR68 | c.795C>G p.F265L | Missense Mutation (SNP) | VAF 39/601 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV53176767, COSV99032164; called by muse, mutect2
- JAKMIP1 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 71/1080 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1023704574, COSV51534944; called by muse, mutect2
- KCNB2 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 63/762 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as rs370327292; called by muse, mutect2
- KCND2 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.234); catalogued as rs1464901287, COSV58580353; called by muse, mutect2
- LY6K | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 119/542 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99456086; called by muse, mutect2, varscan2
- MAGEC1 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs1223933281; called by muse, mutect2, varscan2
- NRK | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV54598432; called by muse, mutect2, varscan2
- PCDHB5 | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as rs782760735, COSV50678024; called by muse, mutect2
- SEMA5A | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101228520; called by muse, mutect2
- TSPAN16 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 49/628 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs768255025, COSV57441936; called by muse, mutect2
- VWDE | c.4546C>T p.R1516* | Nonsense Mutation (SNP) | VAF 54/232 reads (23%) | catalogued as rs113354784; called by muse, mutect2, varscan2
- WASF3 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as rs774059020, COSV58963075, COSV58965240; called by muse, mutect2, varscan2
- XDH | c.1133-1G>A p.X378_splice | Splice Site (SNP) | VAF 52/1000 reads (5%) | catalogued as rs1028214638; called by muse, mutect2
- ACACA | c.4604G>A p.R1535Q | Missense Mutation (SNP) | VAF 36/684 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- ACIN1 | c.3325G>C p.E1109Q | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.365); called by muse, mutect2
- ATP6V0A2 | c.2510T>A p.F837Y | Missense Mutation (SNP) | VAF 59/387 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- B3GALT1 | c.675T>G p.D225E | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CDC42BPG | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 68/455 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCAF4L1 | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 29/339 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); called by muse, mutect2
- DNAH7 | c.9946T>G p.Y3316D | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- DST | c.11392A>G p.T3798A (on ENST00000361203 / NM_001374722.1; = p.T1386A on NM_015548.5) | Missense Mutation (SNP) | VAF 23/340 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2
- FAT4 | c.12185A>C p.H4062P | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- FNDC3A | c.992A>G p.N331S (on ENST00000492622 / NM_001079673.2; = p.N275S on NM_014923.5) | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- GRIN2D | c.3838C>A p.R1280S | Missense Mutation (SNP) | VAF 48/431 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IGDCC4 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2
- LIMS2 | c.246C>A p.F82L (on ENST00000355119 / NM_001161403.3; = p.F106L on NM_017980.4) | Missense Mutation (SNP) | VAF 45/430 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MYO15A | c.1993G>A p.V665M | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RFPL1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- RPS24 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 42/926 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- TAFA1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.01); called by muse, mutect2
- TBC1D2B | c.2439G>T p.L813F | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TDRD15 | c.3803A>G p.N1268S | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- TRPS1 | c.3846A>C p.*1282Yext*5 (on ENST00000220888 / NM_001330599.2; = p.*1295Yext*5 on NM_014112.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- CA5A | c.444C>T p.H148= | Silent (SNP) | VAF 54/552 reads (10%) | catalogued as rs575569678; called by muse, mutect2
- CNTN4 | c.1413C>T p.D471= | Silent (SNP) | VAF 31/379 reads (8%) | catalogued as rs1037405854, COSV61867980; called by muse, mutect2
- FZD10 | c.816C>T p.V272= | Silent (SNP) | VAF 42/496 reads (8%) | called by muse, mutect2
- IKBKB | c.540A>G p.T180= | Silent (SNP) | VAF 40/532 reads (8%) | called by muse, mutect2
- KIF9 | c.2193C>A p.V731= (on ENST00000265529 / NM_001377474.1; = p.V666= on NM_022342.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/486 reads (6%) | called by muse, mutect2
- KPNA2 | c.189G>A p.P63= | Silent (SNP) | VAF 28/243 reads (12%) | catalogued as rs782745827, COSV57857337; called by muse, mutect2, varscan2
- KRTAP20-2 | c.57C>T p.G19= | Silent (SNP) | VAF 110/728 reads (15%) | catalogued as rs1194592664, COSV58182517; called by muse, mutect2, varscan2
- LRRC18 | c.624G>A p.A208= | Silent (SNP) | VAF 117/733 reads (16%) | catalogued as rs750366620, COSV53282970; called by muse, mutect2, varscan2
- PCDHA7 | c.297C>T p.S99= | Silent (SNP) | VAF 90/1066 reads (8%) | catalogued as rs1554134423, COSV65344985; called by muse, mutect2
- POLG | c.3531C>T p.V1177= | Silent (SNP) | VAF 68/896 reads (8%) | catalogued as rs1060504039, COSV51520403; ClinVar: likely benign; called by muse, mutect2
- SLC39A4 | c.519G>A p.A173= (on ENST00000301305 / NM_001374839.1; = p.A148= on NM_017767.3) | Silent (SNP) | VAF 25/338 reads (7%) | catalogued as rs782696621, COSV52779180, COSV99433209; called by muse, mutect2
- STARD9 | c.4758T>C p.Y1586= | Silent (SNP) | VAF 32/405 reads (8%) | called by muse, mutect2
- SYNE1 | c.13551T>C p.G4517= (on ENST00000367255 / NM_182961.4; = p.G4446= on NM_033071.3) | Silent (SNP) | VAF 32/634 reads (5%) | called by muse, mutect2
- TNC | c.2511C>T p.Y837= | Silent (SNP) | VAF 46/426 reads (11%) | catalogued as rs146641282; called by muse, mutect2, varscan2
- TRIM51GP | c.465C>T p.H155= | Silent (SNP) | VAF 21/359 reads (6%) | called by muse, mutect2
- TTN | c.88260T>C p.R29420= (on ENST00000591111; = p.R21996= on NM_003319.4) | Silent (SNP) | VAF 26/440 reads (6%) | catalogued as COSV59972555; called by muse, mutect2
- ZNF493 | c.942T>C p.F314= | Silent (SNP) | VAF 40/516 reads (8%) | called by muse, mutect2
- ABCG8 | c.322+29G>T | Intron (SNP) | VAF 80/665 reads (12%) | called by muse, mutect2, varscan2
- BICDL1 | c.*1144G>A | 3'UTR (SNP) | VAF 30/376 reads (8%) | catalogued as rs545012687; called by muse, mutect2
- JPH4 | c.1152-1042G>A | Intron (SNP) | VAF 45/215 reads (21%) | catalogued as rs552590147; called by muse, mutect2, varscan2
- KIAA1217 | c.354+55812G>T | Intron (SNP) | VAF 45/347 reads (13%) | catalogued as COSV64604022; called by muse, mutect2, varscan2
- LY6K | c.-38C>T | 5'UTR (SNP) | VAF 30/500 reads (6%) | catalogued as rs782374804; called by muse, mutect2
- RN7SL759P | chr15:20572559 C>A | 3'Flank (SNP) | VAF 77/1454 reads (5%) | called by muse, mutect2
